CCDI case PBBZPR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Nasal cavity and middle ear.
https://portal.gdc.cancer.gov/cases/4f9220f4-ac5f-420d-b57a-dcfdcd2b6b60

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Middle ear; Age at diagnosis: 5.4 years (1,986 days).

Biospecimens (3 samples)
- Sample 0DLX4K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLX57: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DLX5G: Tissue type: Tumor; Specimen type: Solid Tissue.
